Gene-level copy-number profile of tumor specimen TCGA-2G-AAEZ-01A from TCGA case TCGA-2G-AAEZ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 38.1 years (13,930 days).
Specimen TCGA-2G-AAEZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fb7ad4db-cc6d-4866-a8f7-be1077bc948c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAEZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/4f7d8698-3a62-49b9-8835-e16dcec8c596

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 548; copy number 2: 7,808; copy number 3: 24,212; copy number 4: 24,443; copy number 5: 154; copy number 6: 246; copy number 7: 548; copy number 8: 213; copy number 9: 15; copy number 10: 32; copy number 11: 158; copy number 12: 25; copy number 13: 224; copy number 14: 20; copy number 15: 49; copy number 17: 6; copy number 24: 171; copy number 36: 29; copy number 48: 6.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–3): RPS3AP15.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,496 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:68,640,798–73,865,890, 80 genes, copy number 7–8 (broad region; genes not listed).
- chr11:55,723,776–58,731,974, 175 genes, copy number 13–24 (broad region; genes not listed).
- chr12:66,767–40,369,285, 865 genes, copy number 7–48 (broad region; genes not listed).
- chr12:54,058,254–55,132,750, 44 genes, copy number 8–13: FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1, VDAC1P5, MUCL1, TESPA1, AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2.
- chr12:68,746,125–76,620,043, 126 genes, copy number 7–14 (broad region; genes not listed).
- chr12:80,099,537–84,449,878, 37 genes, copy number 7–10: OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.2, AC090679.1, AC087888.1.
- chr18:9,708,275–15,066,598, 169 genes, copy number 11–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
